Somatic mutation profile of tumor specimen MMRF_2677_1_BM_CD138pos (aliquot MMRF_2677_1_BM_CD138pos_T1_KHS5U_L13796) from MMRF case MMRF_2677, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.8 years (21,469 days).
Specimen MMRF_2677_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a3d5582-72a5-4671-ad04-05229841a89b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2677_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2677_1_PB_WBC_C3_KHS5U_L13797; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/837c3564-9148-4a82-a4a5-c8a43911f1d2

The open-access MAF lists 117 somatic variants for this specimen: 55 protein-altering or splice-affecting, 12 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, 3'UTR 24, Intron 14, Silent 12, 5'UTR 6, RNA 3, In Frame Del 2, Nonsense Mutation 2, 3'Flank 2, 5'Flank 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 44/183 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 72/263 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANK1 | c.1276C>T p.R426W | Missense Mutation (SNP) | VAF 35/222 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs575994670, COSV55899431; called by muse, mutect2, varscan2
- ARID3B | c.1363C>T p.R455C | Missense Mutation (SNP) | VAF 40/569 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs969183637; called by muse, mutect2
- BRCA1 | c.370A>G p.I124V | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.344); catalogued as rs80357448; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- FGA | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 359/754 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs1397753021, COSV57401396; called by muse, mutect2, varscan2
- GREB1 | c.1690G>A p.V564I | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs778284838, COSV52194132; called by muse, mutect2, varscan2
- HELZ2 | c.6244G>A p.V2082M (on ENST00000467148 / NM_001037335.2; = p.V1513M on NM_033405.3) | Missense Mutation (SNP) | VAF 26/647 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs1459696936; called by muse, mutect2
- IFNGR1 | c.653A>C p.E218A | Missense Mutation (SNP) | VAF 25/244 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.534); catalogued as rs889654179; called by muse, mutect2, varscan2
- IGLL5 | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 46/85 reads (54%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.143); catalogued as rs560170702; called by muse, mutect2, varscan2
- IQCH | c.1364C>T p.P455L | Missense Mutation (SNP) | VAF 28/572 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs866407251; called by muse, mutect2
- KCNN4 | c.794T>C p.I265T | Missense Mutation (SNP) | VAF 108/714 reads (15%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.696); catalogued as rs754006427; called by muse, mutect2, varscan2
- KRI1 | c.733C>T p.L245F | Missense Mutation (SNP) | VAF 120/361 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100469615; called by muse, mutect2, varscan2
- LCA5 | c.1895G>C p.G632A | Missense Mutation (SNP) | VAF 121/495 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as COSV63973290; called by muse, mutect2, varscan2
- METTL11B | c.628G>T p.D210Y | Missense Mutation (SNP) | VAF 16/356 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.183); catalogued as rs1476716172; called by muse, mutect2
- MUC2 | c.3734C>T p.P1245L | Missense Mutation (SNP) | VAF 579/906 reads (64%) | SIFT tolerated (0.12); PolyPhen benign (0.189); catalogued as rs1442745474; called by muse, varscan2
- MYOM3 | c.4181T>C p.I1394T | Missense Mutation (SNP) | VAF 32/362 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756299943; called by muse, mutect2
- NR5A2 | c.475G>A p.D159N (on ENST00000367362 / NM_205860.3; = p.D113N on NM_003822.5) | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs373723203; called by muse, mutect2, varscan2
- OR4K5 | c.218A>G p.Q73R | Missense Mutation (SNP) | VAF 292/641 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as rs764709151; called by muse, mutect2, varscan2
- PABPC4L | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 20/572 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as rs1410503280, COSV69929164; called by muse, mutect2
- RNH1 | c.1052_1054del p.N351del | In Frame Del (DEL) | VAF 332/517 reads (64%) | catalogued as rs771283899; called by pindel, varscan2
- SPTBN1 | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 37/337 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100777272; called by muse, mutect2, varscan2
- STEAP2 | c.142C>T p.R48* | Nonsense Mutation (SNP) | VAF 22/652 reads (3%) | catalogued as rs1355526795, COSV55289268; called by muse, mutect2
- XKR7 | c.1633C>T p.R545W | Missense Mutation (SNP) | VAF 49/283 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1382642489; called by muse, mutect2, varscan2
- ADAM10 | c.675T>A p.Y225* | Nonsense Mutation (SNP) | VAF 79/236 reads (33%) | called by muse, mutect2, varscan2
- ALX1 | c.311T>C p.M104T | Missense Mutation (SNP) | VAF 55/292 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARNTL | c.1522A>G p.R508G (on ENST00000403290 / NM_001297719.2; = p.R507G on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 92/532 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CDHR5 | c.1607C>T p.T536I (on ENST00000358353 / NM_001171968.2; = p.T542I on NM_021924.5) | Missense Mutation (SNP) | VAF 23/520 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); called by muse, mutect2
- CDK20 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 32/344 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- CDR2 | c.406C>A p.L136M | Missense Mutation (SNP) | VAF 46/268 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- CPS1 | c.2059G>C p.V687L | Missense Mutation (SNP) | VAF 30/382 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- CYFIP1 | c.1628T>A p.F543Y | Missense Mutation (SNP) | VAF 20/496 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2
- E2F1 | c.664C>T p.H222Y | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- EPCAM | c.76+8G>A | Splice Region (SNP) | VAF 35/191 reads (18%) | called by muse, mutect2, varscan2
- GPAM | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 107/626 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- GRAMD2B | c.1264A>T p.N422Y | Missense Mutation (SNP) | VAF 42/795 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); called by muse, mutect2
- HNRNPA2B1 | c.65A>G p.K22R (on ENST00000354667 / NM_031243.3; = p.K10R on NM_002137.4) | Missense Mutation (SNP) | VAF 54/276 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- IL11RA | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 49/415 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- IL18RAP | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 20/445 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2
- MAGEC1 | c.1380G>T p.Q460H | Missense Mutation (SNP) | VAF 257/1003 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- MRGPRX2 | c.851C>G p.S284C | Missense Mutation (SNP) | VAF 34/550 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); called by muse, mutect2
- PIK3C2G | c.3439A>T p.I1147F (on ENST00000676171; = p.I1106F on NM_004570.5) | Missense Mutation (SNP) | VAF 182/376 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); called by muse, mutect2, varscan2
- PIK3CD | c.1871A>G p.Y624C | Missense Mutation (SNP) | VAF 44/338 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PRDM1 | c.2128T>A p.C710S | Missense Mutation (SNP) | VAF 232/453 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- ROBO4 | c.560T>G p.V187G | Missense Mutation (SNP) | VAF 51/495 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- SERBP1 | c.287A>G p.Q96R | Missense Mutation (SNP) | VAF 32/221 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- SHISA7 | c.247C>G p.H83D | Missense Mutation (SNP) | VAF 23/516 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.361); called by muse, mutect2
- SLC5A5 | c.1656del p.T553Pfs*151 | Frame Shift Del (DEL) | VAF 15/118 reads (13%) | called by mutect2, pindel, varscan2
- STK32A | c.712T>C p.F238L | Missense Mutation (SNP) | VAF 34/265 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); called by muse, mutect2
- TBCCD1 | c.163_171del p.S55_W57del | In Frame Del (DEL) | VAF 74/530 reads (14%) | called by mutect2, pindel, varscan2
- THBS2 | c.1500G>C p.W500C | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TRPS1 | c.1651C>A p.Q551K (on ENST00000220888 / NM_001330599.2; = p.Q564K on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 279/585 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ZIM3 | c.827A>T p.K276M | Missense Mutation (SNP) | VAF 24/542 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2
- ZNF256 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 22/613 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.298); called by muse, mutect2
- ZNF805 | c.1778A>G p.N593S | Missense Mutation (SNP) | VAF 122/1487 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- ADAMTSL3 | c.3687G>A p.K1229= | Silent (SNP) | VAF 57/521 reads (11%) | catalogued as rs745656919, COSV54472902; called by muse, mutect2, varscan2
- ATP10A | c.2802G>A p.V934= | Silent (SNP) | VAF 62/730 reads (8%) | called by muse, mutect2
- CASD1 | c.1035T>C p.T345= | Silent (SNP) | VAF 10/226 reads (4%) | called by muse, mutect2
- CCDC60 | c.573C>T p.S191= | Silent (SNP) | VAF 53/243 reads (22%) | called by muse, mutect2, varscan2
- COL4A1 | c.1419C>T p.D473= | Silent (SNP) | VAF 94/231 reads (41%) | catalogued as rs140440365, COSV65422031, COSV65423996; called by muse, mutect2, varscan2
- IZUMO1R | c.720G>A p.P240= (on ENST00000440961; = p.P247= on NM_001199206.3) | Silent (SNP) | VAF 58/1351 reads (4%) | catalogued as rs376599967; called by muse, mutect2
- MEGF8 | c.1377C>T p.Y459= | Silent (SNP) | VAF 41/800 reads (5%) | called by muse, mutect2
- NRAP | c.1641T>C p.Y547= (on ENST00000359988 / NM_001322945.2; = p.Y512= on NM_006175.4) | Silent (SNP) | VAF 49/515 reads (10%) | catalogued as COSV100748501; called by muse, mutect2
- SLC12A5 | c.1446G>A p.G482= (on ENST00000454036 / NM_001134771.2; = p.G459= on NM_020708.5) | Silent (SNP) | VAF 70/149 reads (47%) | called by muse, mutect2, varscan2
- TASOR2 | c.6726G>A p.L2242= | Silent (SNP) | VAF 12/244 reads (5%) | catalogued as COSV60167721; called by muse, mutect2
- TNFSF13B | c.324C>G p.V108= | Silent (SNP) | VAF 77/161 reads (48%) | called by muse, mutect2, varscan2
- ZNF74 | c.1482C>T p.H494= | Silent (SNP) | VAF 166/546 reads (30%) | called by muse, mutect2, varscan2
- AC006971.1 | n.1526G>T | RNA (SNP) | VAF 88/318 reads (28%) | called by muse, mutect2, varscan2
- ACTB | c.-27-224G>A | Intron (SNP) | VAF 71/134 reads (53%) | called by muse, mutect2, varscan2
- AHCYL1 | c.*1923G>T | 3'UTR (SNP) | VAF 16/100 reads (16%) | catalogued as rs77332101; called by muse, mutect2, varscan2
- AIM2 | c.*11A>C | 3'UTR (SNP) | VAF 47/272 reads (17%) | called by muse, mutect2, varscan2
- ATP11B | c.*151G>A | 3'UTR (SNP) | VAF 41/255 reads (16%) | called by muse, mutect2, varscan2
- AUNIP | c.-24G>C | 5'UTR (SNP) | VAF 20/117 reads (17%) | called by muse, mutect2, varscan2
- CACNG8 | c.*5992T>A | 3'UTR (SNP) | VAF 18/290 reads (6%) | called by muse, mutect2
- CARS2 | c.1417-255dup | Intron (INS) | VAF 71/370 reads (19%) | called by mutect2, pindel, varscan2
- CCL18 | c.*317T>C | 3'UTR (SNP) | VAF 59/318 reads (19%) | called by muse, mutect2, varscan2
- CEACAM20 | c.-106G>A | 5'UTR (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2
- CEP295 | chr11:93733357 A>C | 3'Flank (SNP) | VAF 19/161 reads (12%) | called by muse, mutect2, varscan2
- CHST1 | c.*746G>A | 3'UTR (SNP) | VAF 152/239 reads (64%) | called by muse, mutect2, varscan2
- CIZ1 | c.2487+82T>G | Intron (SNP) | VAF 8/212 reads (4%) | called by muse, mutect2
- CT83 | c.-95A>T | 5'UTR (SNP) | VAF 122/458 reads (27%) | called by muse, mutect2, varscan2
- CTTNBP2NL | c.*3061G>C | 3'UTR (SNP) | VAF 18/73 reads (25%) | catalogued as rs1427213719; called by muse, mutect2, varscan2
- CUL5 | c.*855del | 3'UTR (DEL) | VAF 22/228 reads (10%) | called by mutect2, pindel
- DDHD2 | c.713-32T>C | Intron (SNP) | VAF 31/151 reads (21%) | called by muse, mutect2, varscan2
- DPP10 | c.*2128T>C | 3'UTR (SNP) | VAF 123/243 reads (51%) | called by muse, mutect2, varscan2
- DYNLL1 | c.-68C>G | 5'UTR (SNP) | VAF 95/226 reads (42%) | called by muse, mutect2, varscan2
- ELAVL4 | chr1:50108883 G>A | 5'Flank (SNP) | VAF 30/63 reads (48%) | called by muse, mutect2, varscan2
- ELN | c.428-136G>A | Intron (SNP) | VAF 18/91 reads (20%) | catalogued as rs367932101; called by muse, mutect2, varscan2
- EMC1 | c.*3390A>C | 3'UTR (SNP) | VAF 64/127 reads (50%) | called by muse, mutect2, varscan2
- FBXO22 | c.*724A>G | 3'UTR (SNP) | VAF 99/1007 reads (10%) | called by muse, mutect2, varscan2
- FRMD1 | c.*362C>G | 3'UTR (SNP) | VAF 41/115 reads (36%) | called by muse, mutect2, varscan2
- GLIS3 | c.*3336del | 3'UTR (DEL) | VAF 10/114 reads (9%) | catalogued as rs200420290, COSV60930434, COSV60933121; ClinVar: uncertain significance; called by pindel, varscan2
- GUK1 | c.-3+201C>G | Intron (SNP) | VAF 213/394 reads (54%) | called by muse, mutect2, varscan2
- LINC02118 | n.106C>T | RNA (SNP) | VAF 84/542 reads (15%) | catalogued as rs536516244; called by muse, mutect2, varscan2
- LNPEP | c.*1367_*1368del | 3'UTR (DEL) | VAF 22/159 reads (14%) | called by pindel, varscan2
- LRTM1 | c.*127_*131del | 3'UTR (DEL) | VAF 31/237 reads (13%) | catalogued as rs781760115; called by pindel, varscan2
- MPI | c.*688del | 3'UTR (DEL) | VAF 33/272 reads (12%) | called by mutect2, pindel, varscan2
- NCAM2 | c.*2519A>T | 3'UTR (SNP) | VAF 11/118 reads (9%) | called by muse, mutect2
- NCK2 | c.*844_*845insACACTA | 3'UTR (INS) | VAF 12/62 reads (19%) | catalogued as rs1553464584, COSV51888014; called by pindel, varscan2
- NTRK3 | c.*12159T>A | 3'UTR (SNP) | VAF 18/512 reads (4%) | called by muse, mutect2
- PKN2 | c.1676+56G>A | Intron (SNP) | VAF 62/158 reads (39%) | catalogued as rs538179355; called by muse, mutect2, varscan2
- PYCR1 | c.-9C>T | 5'UTR (SNP) | VAF 30/183 reads (16%) | called by muse, mutect2, varscan2
- R3HDM4 | c.227-46G>A | Intron (SNP) | VAF 46/250 reads (18%) | catalogued as rs779026297; called by muse, mutect2, varscan2
- RSPO2 | c.*605T>C | 3'UTR (SNP) | VAF 67/147 reads (46%) | called by muse, mutect2, varscan2
- SEL1L3 | c.2585+1342T>C | Intron (SNP) | VAF 14/194 reads (7%) | called by muse, mutect2
- SHISAL2B | c.*79T>C | 3'UTR (SNP) | VAF 468/746 reads (63%) | called by muse, mutect2, varscan2
- SHOX2 | c.347-514G>C | Intron (SNP) | VAF 117/748 reads (16%) | catalogued as COSV67464624; called by muse, mutect2, varscan2
- SLTM | c.*30A>C | 3'UTR (SNP) | VAF 70/1424 reads (5%) | called by muse, mutect2
- SPTBN4 | c.5084+37A>T | Intron (SNP) | VAF 19/490 reads (4%) | called by muse, mutect2
- SYP | c.*4+210C>A | Intron (SNP) | VAF 156/403 reads (39%) | called by muse, mutect2, varscan2
- TRDN | c.*1196T>C | 3'UTR (SNP) | VAF 88/93 reads (95%) | catalogued as rs1399474495; called by muse, mutect2, varscan2
- TRIM46 | c.1886+168A>G | Intron (SNP) | VAF 64/482 reads (13%) | called by muse, mutect2, varscan2
- TRPM8 | c.942+318G>A | Intron (SNP) | VAF 49/239 reads (21%) | called by muse, mutect2, varscan2
- TTC41P | n.85T>C | RNA (SNP) | VAF 68/742 reads (9%) | catalogued as rs532157809; called by muse, mutect2
- TUSC2 | c.-73G>T | 5'UTR (SNP) | VAF 47/428 reads (11%) | called by muse, mutect2, varscan2
- WNK2 | chr9:93319204 G>A | 3'Flank (SNP) | VAF 126/1061 reads (12%) | catalogued as rs201504435, COSV52945919; called by muse, mutect2, varscan2
- ZDBF2 | c.*2214T>G | 3'UTR (SNP) | VAF 29/144 reads (20%) | called by muse, mutect2, varscan2
